Somatic mutation profile of tumor specimen MP2PRT-PARTGF-TMP1-A (aliquot MP2PRT-PARTGF-TMP1-A-1-0-D-A81N-36) from MP2PRT case MP2PRT-PARTGF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.0 years (2,560 days).
Specimen MP2PRT-PARTGF-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f9e822db-7282-4ebb-af7f-7773e5f368ec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARTGF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARTGF-NB1-A-1-0-D-A81N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/80cc3d15-5193-4c93-a90b-38d6cea65f1b

The open-access MAF lists 55 somatic variants for this specimen: 39 protein-altering or splice-affecting, 13 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 13, Nonsense Mutation 5, Intron 3, Nonstop Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGDIG | c.490G>A p.V164I | Missense Mutation (SNP) | VAF 100/362 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs201741302; called by muse, varscan2
- ASB17 | c.537C>G p.I179M | Missense Mutation (SNP) | VAF 24/252 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.037); catalogued as rs778698257; called by muse, mutect2
- CBLC | c.839C>G p.S280* | Nonsense Mutation (SNP) | VAF 25/638 reads (4%) | catalogued as COSV99541865; called by muse, mutect2
- DSG1 | c.2359C>G p.Q787E | Missense Mutation (SNP) | VAF 15/518 reads (3%) | SIFT tolerated (0.46); PolyPhen benign (0.02); catalogued as COSV57132998; called by muse, mutect2
- MPP1 | c.235G>C p.E79Q | Missense Mutation (SNP) | VAF 8/226 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.098); catalogued as COSV65728407; called by muse, mutect2
- PLXNB1 | c.403G>C p.E135Q | Missense Mutation (SNP) | VAF 57/628 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.514); catalogued as COSV56490177, COSV56495380; called by muse, mutect2
- SLC4A7 | c.1684G>A p.E562K | Missense Mutation (SNP) | VAF 65/356 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.092); catalogued as rs989398070; called by muse, mutect2, varscan2
- SUSD6 | c.316G>C p.E106Q | Missense Mutation (SNP) | VAF 19/272 reads (7%) | SIFT tolerated (0.61); PolyPhen benign (0.013); catalogued as rs780496204; called by muse, mutect2
- SYNE2 | c.4013C>G p.S1338C | Missense Mutation (SNP) | VAF 75/311 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV59957003; called by muse, mutect2, varscan2
- UBA2 | c.28G>T p.E10* | Nonsense Mutation (SNP) | VAF 22/384 reads (6%) | catalogued as COSV55825016; called by muse, mutect2
- ZNF276 | c.91C>T p.R31W | Missense Mutation (SNP) | VAF 37/923 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.526); catalogued as rs1055174023; called by muse, mutect2
- AHI1 | c.3495G>A p.M1165I | Missense Mutation (SNP) | VAF 10/320 reads (3%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); called by muse, mutect2
- APBB2 | c.1396G>C p.E466Q (on ENST00000295974 / NM_001166050.2; = p.E467Q on NM_004307.2) | Missense Mutation (SNP) | VAF 12/290 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2
- ARHGAP12 | c.1002T>G p.S334R | Missense Mutation (SNP) | VAF 97/462 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARID5B | c.1489dup p.I497Nfs*31 | Frame Shift Ins (INS) | VAF 172/372 reads (46%) | called by mutect2, varscan2
- CD300H | c.223G>C p.E75Q | Missense Mutation (SNP) | VAF 11/386 reads (3%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.773); called by muse, mutect2
- CFAP54 | c.828G>A p.M276I | Missense Mutation (SNP) | VAF 13/381 reads (3%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2
- CFAP99 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 36/512 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2
- CIITA | c.2014C>T p.Q672* | Nonsense Mutation (SNP) | VAF 17/526 reads (3%) | called by muse, mutect2
- CIP2A | c.1402G>C p.D468H | Missense Mutation (SNP) | VAF 12/187 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2
- CNOT10 | c.1678C>T p.L560F | Missense Mutation (SNP) | VAF 18/268 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CNTN5 | c.1024C>T p.P342S | Missense Mutation (SNP) | VAF 13/367 reads (4%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); called by muse, mutect2
- CNTROB | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 13/433 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.666); called by muse, mutect2
- KDM5C | c.1278G>C p.W426C | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MRPL24 | c.650G>C p.*217Sext*15 | Nonstop Mutation (SNP) | VAF 9/282 reads (3%) | called by muse, mutect2
- NCOR2 | c.1956C>G p.F652L | Missense Mutation (SNP) | VAF 16/491 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- NEXN | c.1597G>C p.E533Q | Missense Mutation (SNP) | VAF 39/228 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- NEXN | c.1669G>C p.E557Q | Missense Mutation (SNP) | VAF 51/244 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- NLRP9 | c.907A>G p.K303E | Missense Mutation (SNP) | VAF 116/326 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- NUP155 | c.774G>C p.K258N (on ENST00000231498 / NM_153485.3; = p.K199N on NM_004298.4) | Missense Mutation (SNP) | VAF 32/392 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); called by muse, mutect2
- PACRG | c.843C>G p.I281M | Missense Mutation (SNP) | VAF 12/359 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- PMEPA1 | c.529G>C p.E177Q | Missense Mutation (SNP) | VAF 29/609 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RYR3 | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 14/365 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.648); called by muse, mutect2
- SLC4A4 | c.2906C>G p.S969* (on ENST00000264485 / NM_001098484.3; = p.S925* on NM_003759.4) | Nonsense Mutation (SNP) | VAF 10/267 reads (4%) | called by muse, mutect2
- SNX7 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 16/305 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- TMEM200C | c.1792A>C p.K598Q | Missense Mutation (SNP) | VAF 173/457 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- ZNF541 | c.3734G>A p.R1245K | Missense Mutation (SNP) | VAF 59/297 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- ZNF595 | c.46G>T p.E16* | Nonsense Mutation (SNP) | VAF 12/264 reads (5%) | called by muse, mutect2
- ZNF814 | c.52G>C p.E18Q | Missense Mutation (SNP) | VAF 11/292 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.887); called by muse, mutect2
- CNTNAP3 | c.2505G>A p.G835= | Silent (SNP) | VAF 19/293 reads (6%) | catalogued as rs559657852; called by muse, mutect2
- CX3CR1 | c.864G>C p.L288= | Silent (SNP) | VAF 15/442 reads (3%) | catalogued as rs1462866251, COSV64193838; called by muse, mutect2
- DTX3 | c.732C>T p.F244= | Silent (SNP) | VAF 19/366 reads (5%) | called by muse, mutect2
- FAM47C | c.93G>A p.A31= | Silent (SNP) | VAF 16/372 reads (4%) | catalogued as rs868908339, COSV63724809; called by muse, mutect2
- MTARC2 | c.636C>G p.L212= | Silent (SNP) | VAF 14/316 reads (4%) | catalogued as COSV63766271; called by muse, mutect2
- NOTCH4 | c.372C>G p.P124= | Silent (SNP) | VAF 21/751 reads (3%) | called by muse, mutect2
- NRAP | c.4515C>G p.L1505= (on ENST00000359988 / NM_001322945.2; = p.L1470= on NM_006175.4) | Silent (SNP) | VAF 71/401 reads (18%) | called by muse, varscan2
- PLEKHG6 | c.2295G>A p.L765= | Silent (SNP) | VAF 24/704 reads (3%) | called by muse, mutect2
- SEPTIN10 | c.774G>A p.P258= | Silent (SNP) | VAF 90/355 reads (25%) | catalogued as rs749478292; called by muse, mutect2, varscan2
- SIGLEC10 | c.1143C>G p.V381= | Silent (SNP) | VAF 14/519 reads (3%) | called by muse, mutect2
- SIK3 | c.198C>T p.I66= (on ENST00000445177 / NM_001366686.2; = p.I72= on NM_025164.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/553 reads (3%) | catalogued as rs1490508297; called by muse, mutect2
- SLC16A4 | c.102G>C p.V34= | Silent (SNP) | VAF 16/327 reads (5%) | called by muse, mutect2
- TPM1 | c.795G>A p.L265= | Silent (SNP) | VAF 16/354 reads (5%) | called by muse, mutect2
- AC010542.3 | c.149-11983C>G | Intron (SNP) | VAF 45/379 reads (12%) | catalogued as rs964328105; called by muse, mutect2, varscan2
- CTNNA2 | c.102+35924G>A | Intron (SNP) | VAF 58/180 reads (32%) | catalogued as rs1302709144; called by muse, mutect2, varscan2
- SCN1B | c.448+129G>A | Intron (SNP) | VAF 26/684 reads (4%) | catalogued as rs1060499899; called by muse, mutect2
